Somatic mutation profile of tumor specimen TCGA-55-A4DF-01A (aliquot TCGA-55-A4DF-01A-11D-A24D-08) from TCGA case TCGA-55-A4DF, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-55-A4DF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 061b49bc-0a5e-4801-bfaf-88ca7231feef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-A4DF-10A (Blood Derived Normal), aliquot TCGA-55-A4DF-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cf7ffbe-9065-4f37-a1ca-b5df87434265

The open-access MAF lists 849 somatic variants for this specimen: 626 protein-altering or splice-affecting, 210 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 545, Silent 210, Nonsense Mutation 52, Splice Site 20, Intron 7, Frame Shift Del 6, RNA 4, Splice Region 2, 3'Flank 1, 5'Flank 1, Nonstop Mutation 1.

Variants (750 of 849; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OTOGL | c.574C>T p.R192* (on ENST00000547103; = p.R183* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as rs397514588, CM1210228, COSV72006650; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1366C>A p.H456N | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100229483; called by muse, mutect2, varscan2
- ABCA7 | c.3611G>A p.G1204E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV99566668; called by muse, mutect2, varscan2
- ABCA7 | c.3976G>T p.E1326* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV99566670; called by muse, mutect2, varscan2
- ABCC10 | c.2374G>T p.D792Y (on ENST00000372530 / NM_001198934.2; = p.D764Y on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55085544; called by muse, mutect2, varscan2
- ABCC10 | c.2482G>A p.E828K (on ENST00000372530 / NM_001198934.2; = p.E800K on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs763215687, COSV99767981; called by muse, mutect2, varscan2
- ABCC10 | c.2578G>T p.E860* (on ENST00000372530 / NM_001198934.2; = p.E832* on NM_033450.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV55087083, COSV99767984; called by muse, mutect2, varscan2
- ABCF3 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 21/371 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV53047126; called by muse, mutect2
- ACAN | c.7409G>T p.C2470F (on ENST00000560601 / NM_001369268.1; = p.C2394F on NM_001135.3) | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100613871; called by muse, mutect2, varscan2
- ADAM19 | c.2129C>A p.A710D | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.198); catalogued as COSV99978480; called by muse, mutect2, varscan2
- ADAMTS19 | c.1528C>T p.H510Y | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99180754; called by muse, mutect2, varscan2
- ADAMTS20 | c.4141A>G p.R1381G | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101166396; called by muse, mutect2
- ADAMTS7 | c.3571G>A p.E1191K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.031); catalogued as COSV101183263; called by muse, mutect2, varscan2
- ADAR | c.1602-1G>C p.X534_splice | Splice Site (SNP) | VAF 12/113 reads (11%) | catalogued as COSV52713846, COSV99426716; called by muse, mutect2, varscan2
- ADGRE3 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0.027); catalogued as COSV99506704; called by muse, mutect2, varscan2
- ADGRF3 | c.1157C>G p.S386C (on ENST00000311519 / NM_001145168.1; = p.S187C on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as rs758356786, COSV100275453; called by muse, mutect2, varscan2
- ADGRL4 | c.1749+1G>C p.X583_splice | Splice Site (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100876553, COSV66061924; called by muse, mutect2, varscan2
- ADHFE1 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs542850663, COSV52554899, COSV99398192; called by muse, mutect2, varscan2
- AEN | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.238); catalogued as COSV100237626; called by muse, mutect2
- AHNAK | c.15022G>T p.E5008* | Nonsense Mutation (SNP) | VAF 22/188 reads (12%) | catalogued as COSV99945285, COSV99949612, COSV99949835; called by muse, mutect2, varscan2
- AKAP11 | c.5404+1G>T p.X1802_splice | Splice Site (SNP) | VAF 31/54 reads (57%) | catalogued as COSV99214344; called by muse, mutect2, varscan2
- AKAP8 | c.1250C>A p.T417N | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as COSV99512184; called by muse, mutect2, varscan2
- AKR7A3 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100853835; called by muse, mutect2, varscan2
- ALKBH1 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 68/425 reads (16%) | catalogued as COSV99380790; called by muse, mutect2, varscan2
- ALS2CL | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as COSV100015321; called by muse, mutect2
- AMPH | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57734569; called by muse, mutect2, varscan2
- ANKRD11 | c.2579C>T p.S860L | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs145730800; called by muse, mutect2, varscan2
- ANKRD27 | c.2977C>T p.H993Y | Missense Mutation (SNP) | VAF 30/450 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); catalogued as COSV60134641; called by muse, mutect2
- ANKRD34B | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.054); catalogued as rs748437063, COSV100103657; called by muse, mutect2, varscan2
- ANKRD45 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV100322674, COSV60960562; called by muse, mutect2, varscan2
- ANO2 | c.2411C>G p.S804C (on ENST00000356134 / NM_001278597.3; = p.S808C on NM_001278596.3) | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as COSV59042929; called by muse, mutect2, varscan2
- ANO3 | c.2663G>A p.R888K | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1414040866, COSV99885723; called by muse, mutect2, varscan2
- AP1B1 | c.2634G>C p.Q878H | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV100434833; called by muse, mutect2
- APBB2 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.836); catalogued as COSV99924113; called by muse, mutect2, varscan2
- APOBR | c.2170G>A p.D724N (on ENST00000431282; = p.D733N on NM_018690.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs1172419839, COSV100112939; called by mutect2, varscan2
- ARHGAP12 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV100260906; called by muse, mutect2, varscan2
- ARHGAP33 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs1472037934, COSV99140030; called by muse, mutect2, varscan2
- ARID4B | c.2362G>C p.V788L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV99936338; called by muse, mutect2, varscan2
- ARID4B | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV99936340; called by muse, mutect2
- ARSL | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV101140781; called by muse, mutect2, varscan2
- ASCC2 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100316504; called by muse, mutect2, varscan2
- ASIC5 | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101611178, COSV73332580; called by muse, mutect2, varscan2
- ATAD5 | c.4759G>A p.D1587N | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100430225; called by muse, mutect2, varscan2
- ATG2B | c.1778C>T p.S593L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs765629673, COSV100738263; called by muse, mutect2, varscan2
- ATG5 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV100576662; called by muse, mutect2
- ATP13A3 | c.2387C>G p.T796R | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV99757651; called by muse, mutect2, varscan2
- ATP8B3 | c.3400C>G p.L1134V | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs893729077, COSV100034965; called by muse, mutect2, varscan2
- ATR | c.6691G>C p.D2231H | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV100638587, COSV99052449; called by muse, mutect2
- B4GALT2 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV99356646; called by muse, mutect2, varscan2
- BDP1 | c.5021C>G p.S1674* | Nonsense Mutation (SNP) | VAF 56/198 reads (28%) | catalogued as COSV100703529; called by muse, mutect2, varscan2
- BPNT2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.116); catalogued as COSV99389120; called by muse, mutect2, varscan2
- BRCA2 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101204650; called by muse, mutect2, varscan2
- BRCA2 | c.9722C>G p.S3241C | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.919); catalogued as rs398122621, COSV101200921; ClinVar: uncertain significance; called by muse, mutect2
- BTK | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100437928; called by muse, mutect2, varscan2
- C11orf53 | c.866G>C p.*289Sext*49 | Nonstop Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99724906; called by muse, mutect2, varscan2
- C12orf4 | c.1140G>T p.R380S | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99712944; called by muse, mutect2, varscan2
- C12orf60 | c.615G>C p.K205N | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV99966984; called by muse, mutect2, varscan2
- C1QB | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100152818; called by muse, mutect2, varscan2
- C1orf94 | c.1084A>G p.K362E (on ENST00000488417 / NM_001134734.2; = p.K172E on NM_032884.5) | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100975235; called by muse, mutect2, varscan2
- C7 | c.341C>A p.A114D | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as COSV100496604, COSV57478242; called by muse, mutect2, varscan2
- C9orf24 | c.136-1G>C p.X46_splice | Splice Site (SNP) | VAF 18/241 reads (7%) | catalogued as COSV99898133; called by muse, mutect2
- CA8 | c.579G>T p.G193= | Splice Region (SNP) | VAF 10/96 reads (10%) | catalogued as COSV100527301, COSV58771444; called by muse, mutect2, varscan2
- CA8 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100527303; called by muse, mutect2, varscan2
- CACNA1A | c.6293C>A p.S2098Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100803217; called by muse, mutect2, varscan2
- CACNA2D1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV100666783, COSV100667330; called by muse, mutect2, varscan2
- CACNA2D4 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99766513; called by muse, mutect2
- CADPS | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs1194895026, COSV99340932; called by muse, mutect2, varscan2
- CALD1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.526); catalogued as COSV100724575; called by muse, mutect2
- CAMKK1 | c.1333A>T p.T445S | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV99340269, COSV99340575; called by muse, mutect2, varscan2
- CAMP | c.454G>A p.E152K (on ENST00000296435; = p.E149K on NM_004345.5) | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.143); catalogued as COSV99601324; called by muse, mutect2
- CAPN15 | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99562834; called by muse, mutect2, varscan2
- CASS4 | c.1975C>T p.Q659* | Nonsense Mutation (SNP) | VAF 9/91 reads (10%) | catalogued as COSV100824534; called by muse, mutect2, varscan2
- CASZ1 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); catalogued as rs1344522422, COSV100681332; called by muse, mutect2, varscan2
- CATSPERB | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56431572, COSV99831781; called by muse, mutect2, varscan2
- CBX5 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.942); catalogued as COSV52938770; called by muse, mutect2
- CBY2 | c.598T>C p.W200R | Missense Mutation (SNP) | VAF 58/99 reads (59%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); catalogued as COSV100137841; called by muse, mutect2, varscan2
- CC2D1A | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100528706; called by muse, mutect2
- CCDC42 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.1); catalogued as COSV99549932; called by muse, mutect2, varscan2
- CCDC6 | c.1227C>G p.I409M | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as COSV54057525; called by muse, mutect2, varscan2
- CCDC90B | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.003); catalogued as COSV99475436; called by muse, mutect2
- CCNF | c.1528C>G p.L510V | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV99564169; called by muse, mutect2, varscan2
- CCP110 | c.2428C>G p.L810V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101195347; called by muse, mutect2, varscan2
- CD3E | c.302G>C p.R101T | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100689086; called by muse, mutect2
- CDC5L | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV101015201; called by muse, mutect2, varscan2
- CDH1 | c.1222G>C p.A408P | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55732641, COSV99932673; called by muse, mutect2, varscan2
- CDH10 | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 52/279 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs760893659, COSV100053135; called by muse, mutect2, varscan2
- CDH20 | c.1300G>C p.G434R | Missense Mutation (SNP) | VAF 35/298 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV99406559; called by muse, mutect2, varscan2
- CELSR2 | c.5254G>T p.G1752C | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV54780983, COSV99604740; called by muse, mutect2, varscan2
- CETP | c.508C>T p.H170Y | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV99570347; called by muse, mutect2, varscan2
- CFAP69 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 58/302 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV100290451; called by muse, varscan2
- CFAP69 | c.2539A>G p.K847E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV100290454; called by muse, mutect2, varscan2
- CFAP92 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 22/99 reads (22%) | catalogued as COSV54046683; called by muse, mutect2, varscan2
- CHGB | c.264C>A p.D88E | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.268); catalogued as COSV100973102; called by muse, mutect2, varscan2
- CHRNA4 | c.744C>G p.I248M | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV100937484; called by muse, mutect2
- CHRNB2 | c.450C>G p.I150M | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100872681; called by muse, mutect2, varscan2
- CHST1 | c.402C>G p.F134L | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.829); catalogued as COSV100346533, COSV57321692; called by muse, mutect2
- CHST8 | c.1142C>A p.A381E | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV52856269, COSV99381656; called by muse, mutect2, varscan2
- CLCA4 | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99760824; called by muse, mutect2
- CLCN4 | c.437C>G p.A146G | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV101074066; called by muse, mutect2, varscan2
- CLDN18 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs1278153754, COSV59302005; called by muse, mutect2, varscan2
- CLEC12B | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs759310555, COSV100138939, COSV100139109; called by muse, mutect2, varscan2
- CNGA4 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99792512; called by muse, mutect2, varscan2
- CNGA4 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | catalogued as COSV101171880; called by muse, mutect2
- CNKSR3 | c.868A>C p.K290Q | Missense Mutation (SNP) | VAF 66/116 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101401412; called by muse, mutect2, varscan2
- CNOT1 | c.934-1G>C p.X312_splice | Splice Site (SNP) | VAF 23/83 reads (28%) | catalogued as COSV100410073; called by muse, mutect2, varscan2
- CNTNAP5 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV101444235, COSV70494453; called by muse, mutect2
- COL12A1 | c.4330C>G p.L1444V | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100486543; called by muse, mutect2
- COL1A1 | c.4199C>T p.A1400V | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV99868163; called by muse, mutect2, varscan2
- COL22A1 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs753469570, COSV100280787; called by mutect2, varscan2
- COL5A2 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100880816, COSV66412925; called by muse, mutect2, varscan2
- COLGALT2 | c.759C>G p.F253L | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100730866; called by muse, mutect2, varscan2
- COMMD6 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100869898; called by muse, mutect2, varscan2
- COPG1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100135219, COSV100135954; called by muse, mutect2, varscan2
- CRNKL1 | c.1456-1G>T p.X486_splice | Splice Site (SNP) | VAF 31/122 reads (25%) | catalogued as COSV101056908, COSV101057139; called by muse, mutect2, varscan2
- CRYBB1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99316214; called by muse, mutect2, varscan2
- CSE1L | c.1974A>T p.E658D | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99522268; called by muse, mutect2, varscan2
- CSF2RA | c.242G>C p.C81S | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100817958; called by muse, mutect2, varscan2
- CSKMT | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as rs1219153677, COSV100649285; called by muse, mutect2, varscan2
- CSMD2 | c.1442C>T p.T481I | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV99595326; called by muse, mutect2, varscan2
- CSMD3 | c.10882A>C p.S3628R (on ENST00000297405 / NM_001363185.1; = p.S3459R on NM_052900.3) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99847727; called by muse, mutect2, varscan2
- CTNNA3 | c.2363A>C p.E788A | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV101041637; called by muse, mutect2, varscan2
- CTNND2 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 119/604 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs750967819, COSV100476170, COSV58876698; called by muse, varscan2
- CTPS1 | c.899C>G p.S300C | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs201674363, COSV101009406; called by muse, mutect2, varscan2
- CTTNBP2 | c.2078C>A p.P693H | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99354870; called by muse, mutect2, varscan2
- CTTNBP2NL | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54746080, COSV99600278; called by muse, mutect2, varscan2
- CWF19L2 | c.2430C>G p.I810M | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99979867; called by muse, mutect2, varscan2
- CYC1 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769424627, COSV100010134; called by mutect2, varscan2
- CYC1 | c.882G>C p.M294I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100010615; called by muse, mutect2, varscan2
- CYP11B2 | c.1132G>T p.V378L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100011396; called by muse, mutect2, varscan2
- CYP4F8 | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1419560498, COSV100358244; called by muse, mutect2, varscan2
- DACH1 | c.1742C>G p.S581C (on ENST00000619232 / NM_001366712.1; = p.S327C on NM_004392.6) | Missense Mutation (SNP) | VAF 62/421 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.005); catalogued as COSV100499256, COSV57503837; called by muse, mutect2, varscan2
- DCD | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99514124; called by muse, mutect2, varscan2
- DCST2 | c.1291T>C p.W431R | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99792250; called by muse, mutect2, varscan2
- DCTN4 | c.1168G>C p.D390H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV69781755; called by muse, mutect2, varscan2
- DDHD2 | c.1969C>G p.Q657E | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV101240806; called by muse, mutect2, varscan2
- DDX60 | c.1312C>A p.L438I | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as COSV101190659; called by muse, mutect2
- DEPDC7 | c.514G>C p.E172Q (on ENST00000241051 / NM_001077242.2; = p.E163Q on NM_139160.2) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV99572915; called by muse, mutect2
- DGKE | c.546C>G p.F182L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV52350144, COSV99400728, COSV99401206; called by muse, mutect2, varscan2
- DGKH | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99819571; called by muse, mutect2, varscan2
- DGKK | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.103); catalogued as COSV101053213; called by muse, mutect2, varscan2
- DHTKD1 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as rs1366051858, COSV99536935; called by muse, mutect2, varscan2
- DMBT1 | c.5221C>T p.Q1741* (on ENST00000338354 / NM_001377530.1; = p.Q984* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 41/171 reads (24%) | catalogued as COSV100354108; called by muse, mutect2, varscan2
- DMD | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99926175; called by muse, mutect2, varscan2
- DMXL1 | c.4205C>T p.S1402F | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60712153; called by muse, mutect2, varscan2
- DNAH17 | c.5673G>C p.Q1891H | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101103476, COSV67751411; called by muse, mutect2, varscan2
- DNAH3 | c.262C>A p.R88S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV99770663; called by muse, mutect2, varscan2
- DNAH9 | c.2869T>A p.F957I | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99308149; called by muse, mutect2, varscan2
- DOCK10 | c.3821C>T p.S1274L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV99291646; called by muse, mutect2, varscan2
- DOCK6 | c.6040C>G p.L2014V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99626713; called by muse, mutect2, varscan2
- DPM1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100857689, COSV100857760; called by muse, mutect2, varscan2
- DPP10 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59745617; called by muse, mutect2, varscan2
- DSEL | c.575A>G p.D192G | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100026111; called by muse, mutect2, varscan2
- DTX3 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as rs771323518, COSV99678290; called by muse, mutect2, varscan2
- DUSP12 | c.963G>C p.K321N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV100909775; called by muse, mutect2, varscan2
- DYNC2LI1 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); catalogued as COSV99571591; called by muse, mutect2, varscan2
- EDEM3 | c.2081C>T p.S694L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as COSV100545676; called by mutect2, varscan2
- EDNRB | c.1315C>G p.L439V (on ENST00000377211 / NM_001201397.1; = p.L349V on NM_000115.5) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV104398502, COSV57519484; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.05); catalogued as COSV100668865; called by muse, mutect2, varscan2
- EFCAB6 | c.3556G>C p.E1186Q | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.341); catalogued as COSV99414421; called by muse, mutect2, varscan2
- EHMT1 | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100604275; called by muse, mutect2, varscan2
- EIF3A | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100974822; called by muse, mutect2, varscan2
- EIF4G1 | c.4424C>G p.S1475C (on ENST00000346169 / NM_198241.3; = p.S1280C on NM_004953.5) | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100072298; called by muse, mutect2, varscan2
- ELFN2 | c.2165A>G p.D722G | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.585); catalogued as COSV101297646; called by muse, mutect2, varscan2
- ELSPBP1 | c.327A>T p.K109N | Missense Mutation (SNP) | VAF 70/121 reads (58%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV100353783; called by muse, mutect2, varscan2
- EME2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV99457439; called by muse, mutect2, varscan2
- EMILIN1 | c.1663G>C p.E555Q | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.629); catalogued as COSV99566545; called by muse, mutect2, varscan2
- EML3 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99606119; called by muse, mutect2, varscan2
- ENOX1 | c.1059C>G p.F353L | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV99817193; called by muse, mutect2, varscan2
- ENTPD4 | c.781A>C p.I261L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100652791; called by muse, mutect2, varscan2
- EPB41L3 | c.1502G>A p.G501E | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs775911998, COSV59469381; called by muse, mutect2, varscan2
- EPHA1 | c.146A>T p.D49V | Missense Mutation (SNP) | VAF 67/398 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99314700; called by muse, mutect2, varscan2
- EPHA2 | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376424805; called by muse, mutect2, varscan2
- EPHA2 | c.2269G>A p.D757N | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100626297; called by muse, mutect2, varscan2
- EPHA2 | c.2067G>A p.M689I | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100626298; called by muse, mutect2, varscan2
- EPHA4 | c.1325C>A p.S442* | Nonsense Mutation (SNP) | VAF 10/97 reads (10%) | catalogued as COSV56029398, COSV99917508; called by muse, mutect2, varscan2
- EPHA7 | c.1771del p.E591Kfs*38 | Frame Shift Del (DEL) | VAF 32/99 reads (32%) | catalogued as COSV100994517; called by mutect2, pindel, varscan2
- EPHA8 | c.2650C>A p.R884S | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as COSV51272991, COSV99385718; called by muse, mutect2, varscan2
- EPS15 | c.365G>C p.W122S | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100869079, COSV100869089; called by muse, mutect2, varscan2
- EPS8 | c.2374G>T p.E792* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99843686; called by muse, mutect2, varscan2
- ERCC4 | c.404G>C p.R135T | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as rs772606808, COSV100319119; called by muse, mutect2, varscan2
- ERVFRD-1 | c.257T>C p.M86T | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1455409491, COSV100977431; called by muse, mutect2, varscan2
- ESCO1 | c.1151C>G p.S384* | Nonsense Mutation (SNP) | VAF 23/140 reads (16%) | catalogued as COSV99332597; called by muse, mutect2, varscan2
- ESCO2 | c.1531G>C p.E511Q | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100533410; called by muse, mutect2
- ESF1 | c.2501C>G p.S834C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52520757, COSV99176317; called by muse, mutect2, varscan2
- EXO1 | c.1715A>G p.H572R | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV100800180; called by muse, mutect2, varscan2
- EXOC3L1 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV99333962; called by muse, mutect2, varscan2
- F8 | c.5101G>A p.E1701K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as CM054678, CM1212741, COSV100811962; called by muse, mutect2, varscan2
- FAM111A | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV64655570; called by muse, mutect2, varscan2
- FAM171A1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1290535497, COSV65313996, COSV65318878; called by muse, mutect2, varscan2
- FAM47C | c.1863G>T p.E621D | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as COSV100792947; called by muse, mutect2, varscan2
- FAM83B | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100175022, COSV60922212; called by muse, mutect2, varscan2
- FANCM | c.4373T>G p.F1458C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.19); catalogued as COSV99951648; called by muse, mutect2, varscan2
- FBN2 | c.6653C>G p.S2218* | Nonsense Mutation (SNP) | VAF 40/81 reads (49%) | catalogued as COSV99330675; called by muse, mutect2, varscan2
- FBXL2 | c.657+1G>T p.X219_splice | Splice Site (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99372281; called by muse, mutect2, varscan2
- FCGR3A | c.713G>C p.R238T | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV100914719; called by muse, mutect2, varscan2
- FETUB | c.346C>G p.Q116E | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV99408938, COSV99409147; called by muse, mutect2, varscan2
- FHOD1 | c.910C>G p.Q304E | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV99264515; called by muse, mutect2, varscan2
- FIGNL1 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs1261788895, COSV100794957; called by muse, mutect2, varscan2
- FIGNL1 | c.267G>T p.L89F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV100794960; called by muse, mutect2, varscan2
- FLI1 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99858121; called by muse, mutect2
- FMN2 | c.3344G>A p.G1115E | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs1248062589, COSV100147120; called by muse, mutect2, varscan2
- FMNL3 | c.2959G>C p.E987Q | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV53308153; called by muse, mutect2, varscan2
- FMO3 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as CM992886, COSV63008080; called by muse, mutect2
- FN1 | c.6819G>A p.M2273I (on ENST00000359671 / NM_001365524.2; = p.M2242I on NM_002026.4) | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as rs1372226584, COSV60565626; called by muse, mutect2, varscan2
- FOLH1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57048302, COSV99923951; called by muse, mutect2, varscan2
- FOXA1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV99163511; called by muse, varscan2
- GABRA2 | c.1095C>G p.N365K | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.487); catalogued as COSV100734761; called by muse, mutect2, varscan2
- GAK | c.2432C>T p.S811F | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100034064; called by muse, mutect2, varscan2
- GALNT2 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755413572, COSV64195168; called by muse, mutect2, varscan2
- GAPDHS | c.791C>G p.S264* | Nonsense Mutation (SNP) | VAF 26/344 reads (8%) | catalogued as COSV99722498; called by muse, mutect2
- GATA3 | c.1192A>T p.R398* | Nonsense Mutation (SNP) | VAF 53/183 reads (29%) | catalogued as COSV100651246, COSV99062076; called by muse, mutect2, varscan2
- GATAD2B | c.1720G>T p.E574* | Nonsense Mutation (SNP) | VAF 19/147 reads (13%) | catalogued as COSV100897894, COSV100898018; called by muse, mutect2, varscan2
- GBA2 | c.2407G>A p.G803R | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100803500; called by muse, mutect2
- GDAP1L1 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV100697677; called by muse, mutect2
- GDI1 | c.350A>C p.Y117S | Missense Mutation (SNP) | VAF 122/244 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.08); catalogued as COSV100870737; called by muse, varscan2
- GEMIN4 | c.2611C>T p.R871C | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs200388628, COSV100021606; called by muse, mutect2, varscan2
- GFI1 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV99647640; called by muse, mutect2, varscan2
- GFOD2 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99263723; called by muse, mutect2, varscan2
- GHSR | c.919G>T p.V307L | Missense Mutation (SNP) | VAF 49/285 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as rs200570638, COSV53841292, COSV99577265; called by muse, mutect2, varscan2
- GIP | c.142C>G p.R48G | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV100656964; called by muse, mutect2, varscan2
- GJA4 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 6/66 reads (9%) | catalogued as COSV100654767; called by muse, mutect2
- GK5 | c.1049-1G>T p.X350_splice | Splice Site (SNP) | VAF 18/206 reads (9%) | catalogued as COSV101242345; called by muse, mutect2
- GNAO1 | c.458C>A p.A153D | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99341791; called by muse, mutect2, varscan2
- GOLGA2 | c.108G>C p.K36N | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV60791730; called by muse, mutect2, varscan2
- GOLGB1 | c.6529C>T p.Q2177* | Nonsense Mutation (SNP) | VAF 51/110 reads (46%) | catalogued as COSV100511534; called by muse, mutect2, varscan2
- GON4L | c.4192G>C p.D1398H | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.621); catalogued as COSV99675774; called by muse, mutect2, varscan2
- GPAM | c.1780C>G p.L594V | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100788429; called by muse, mutect2, varscan2
- GPATCH4 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV100576998; called by muse, mutect2, varscan2
- GPC3 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV100893570; called by muse, mutect2, varscan2
- GPD2 | c.1007G>T p.S336I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100133668; called by muse, mutect2, varscan2
- GPR37 | c.1602C>G p.S534R | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV100391168; called by muse, mutect2, varscan2
- GPX1 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV101346334; called by muse, mutect2, varscan2
- GPX1 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV101346336; called by muse, mutect2, varscan2
- GRAP2 | c.407C>A p.S136Y | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100703153; called by muse, mutect2, varscan2
- GRIN2A | c.1473T>A p.N491K | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100411075; called by muse, mutect2, varscan2
- GRIN2A | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs757262372, COSV58023775; called by muse, mutect2, varscan2
- GRM4 | c.2590G>T p.V864F | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV100946883; called by muse, mutect2, varscan2
- GSTM2 | c.93G>C p.K31N | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV53982802, COSV53983683, COSV99598404; called by muse, mutect2, varscan2
- GTF2IRD1 | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV56088111; called by muse, mutect2
- GTF3C6 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100328798; called by muse, mutect2, varscan2
- H3C1 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 61/104 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.645); catalogued as COSV55119393, COSV99772202; called by muse, mutect2, varscan2
- H6PD | c.759C>G p.F253L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101072523; called by muse, mutect2, varscan2
- HARS1 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV56905582, COSV56906207; called by muse, mutect2
- HDAC10 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as COSV99299323, COSV99299689; called by muse, mutect2, varscan2
- HDX | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV99948045; called by muse, mutect2, varscan2
- HECW1 | c.3532G>A p.E1178K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV101224300; called by muse, mutect2, varscan2
- HERC2 | c.14452G>A p.D4818N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99876722; called by muse, varscan2
- HEXIM1 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs903988968, COSV100203564, COSV60176961; called by muse, mutect2, varscan2
- HEXIM1 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 14/188 reads (7%) | catalogued as COSV100203606; called by muse, mutect2
- HHIPL2 | c.1111C>G p.Q371E | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV100597111, COSV99072535; called by muse, mutect2, varscan2
- HIPK1 | c.3587G>C p.G1196A (on ENST00000369558 / NM_001369806.1; = p.G802A on NM_181358.2) | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as COSV100479679; called by muse, mutect2, varscan2
- HIPK3 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100306070; called by muse, mutect2, varscan2
- HIVEP1 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 10/95 reads (11%) | catalogued as COSV101045746; called by muse, mutect2, varscan2
- HLA-A | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.98); catalogued as COSV65145225; called by muse, mutect2, varscan2
- HNRNPA1 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99267879; called by muse, mutect2, varscan2
- HNRNPU | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as rs1322682341, COSV99310709; called by muse, mutect2, varscan2
- HORMAD1 | c.178+2T>G p.X60_splice | Splice Site (SNP) | VAF 36/91 reads (40%) | catalogued as COSV100464433; called by muse, mutect2, varscan2
- HSPA6 | c.1873G>T p.G625C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.928); catalogued as COSV100554329; called by muse, mutect2, varscan2
- HSPA6 | c.1874G>T p.G625V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV59059999; called by muse, mutect2, varscan2
- HSPH1 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.722); catalogued as COSV100185172; called by muse, mutect2, varscan2
- ID3 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101000798; called by muse, mutect2, varscan2
- IGKV1-16 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs371996207; called by muse, mutect2, varscan2
- IGSF22 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100080413; called by muse, mutect2, varscan2
- IGSF9B | c.3544C>T p.R1182W | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs765118637, COSV58063635; called by muse, mutect2, varscan2
- IL1RAPL1 | c.284G>C p.R95T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100150514; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100782039, COSV61144719; called by muse, mutect2, varscan2
- INPP5B | c.1741A>G p.T581A (on ENST00000373023; = p.T501A on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100886626; called by muse, mutect2, varscan2
- INSRR | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV100948096, COSV63870623; called by mutect2, varscan2
- IPP | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV63433374; called by muse, mutect2, varscan2
- ITGAE | c.2765C>T p.S922L | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as COSV53995028, COSV99561549; called by muse, varscan2
- ITPR2 | c.6177G>C p.E2059D | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV101190165, COSV67274957; called by muse, mutect2, varscan2
- KATNBL1 | c.44A>G p.N15S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs779923618, COSV99854532; called by muse, mutect2
- KCNA4 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100069039; called by muse, mutect2
- KCNAB2 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs1206687594, COSV99379581; called by muse, mutect2
- KCNK2 | c.370G>T p.A124S (on ENST00000444842 / NM_001017425.3; = p.A109S on NM_014217.4) | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV101222339; called by muse, mutect2, varscan2
- KCNU1 | c.2384C>A p.S795Y | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV101299426; called by muse, mutect2, varscan2
- KDM2B | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100997662; called by muse, mutect2, varscan2
- KDM5A | c.3888C>G p.I1296M | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV101239062; called by muse, mutect2, varscan2
- KEAP1 | c.1708+1G>T p.X570_splice | Splice Site (SNP) | VAF 22/45 reads (49%) | catalogued as COSV99408302; called by muse, mutect2, varscan2
- KIAA1522 | c.2518C>T p.P840S (on ENST00000373480 / NM_001198972.2; = p.P899S on NM_020888.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as COSV53864192, COSV99615129; called by muse, mutect2, varscan2
- KIN | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.029); catalogued as COSV101092695; called by muse, mutect2, varscan2
- KIRREL2 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 150/302 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as rs1400062896, COSV99384454; called by muse, mutect2, varscan2
- KITLG | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as COSV99933565; called by muse, mutect2, varscan2
- KLHL12 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); catalogued as COSV100766176; called by muse, mutect2, varscan2
- KRT35 | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55843768; called by muse, mutect2, varscan2
- KRT37 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 93/171 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs759718832, COSV99845713; called by muse, mutect2, varscan2
- KRT6B | c.676G>C p.D226H | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99361007; called by muse, mutect2, varscan2
- LAMA1 | c.2231G>T p.C744F | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101057732; called by muse, mutect2, varscan2
- LAMC1 | c.3544G>C p.E1182Q | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.311); catalogued as COSV99280458; called by muse, mutect2, varscan2
- LBX2 | c.458C>T p.S153L (on ENST00000377566 / NM_001282430.2; = p.S149L on NM_001009812.2) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV52036379; called by muse, varscan2
- LBX2 | c.399C>G p.F133L (on ENST00000377566 / NM_001282430.2; = p.F129L on NM_001009812.2) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99282379; called by muse, varscan2
- LCT | c.4379G>C p.G1460A | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99930469; called by muse, mutect2, varscan2
- LHFPL1 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV64333224; called by muse, mutect2, varscan2
- LILRA5 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100007105; called by muse, mutect2, varscan2
- LILRB5 | c.1495G>T p.G499W (on ENST00000449561 / NM_001081442.3; = p.G498W on NM_006840.5) | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV100300784, COSV100300815; called by muse, mutect2, varscan2
- LMNB2 | c.568G>T p.G190C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV57586396; called by muse, mutect2, varscan2
- LPP | c.1303C>G p.Q435E | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV100448342; called by muse, mutect2
- LRP8 | c.2600G>A p.R867K | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.955); catalogued as COSV100036912; called by muse, mutect2, varscan2
- LRRC2 | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV99947681; called by muse, mutect2
- LRRC31 | c.1083G>T p.R361S | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as COSV99247099; called by muse, mutect2, varscan2
- LRRC7 | c.3919G>T p.D1307Y (on ENST00000651989 / NM_001370785.2; = p.D1274Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99229781; called by muse, mutect2, varscan2
- LRRC74A | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53610842; called by muse, mutect2, varscan2
- LRRIQ3 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs762964869, COSV100599489; called by muse, mutect2, varscan2
- LRRTM3 | c.291C>G p.I97M | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100791918; called by muse, mutect2, varscan2
- LTBP1 | c.3113-1G>C p.X1038_splice (on ENST00000404816 / NM_206943.4; = p.X712_splice on NM_000627.4) | Splice Site (SNP) | VAF 6/27 reads (22%) | catalogued as COSV55381613, COSV99698839; called by muse, mutect2, varscan2
- LY75 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99716670; called by muse, mutect2
- LYSMD2 | c.389C>G p.S130C | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99591234; called by muse, mutect2, varscan2
- MAGEA11 | c.1044G>T p.E348D | Missense Mutation (SNP) | VAF 50/414 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV100290718; called by muse, mutect2, varscan2
- MAGEC1 | c.2290C>A p.Q764K | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV53582572, COSV99596521; called by muse, mutect2, varscan2
- MANBA | c.1441G>C p.E481Q (on ENST00000642252; = p.E435Q on NM_005908.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99899199; called by muse, mutect2, varscan2
- MAP1B | c.6349G>T p.E2117* | Nonsense Mutation (SNP) | VAF 72/199 reads (36%) | catalogued as COSV99702942; called by muse, mutect2, varscan2
- MAP3K3 | c.401C>G p.S134C | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as COSV100675638; called by muse, mutect2, varscan2
- MAPK8 | c.736C>G p.P246A | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100827549; called by muse, mutect2, varscan2
- MAPKAPK2 | c.145A>C p.K49Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV99686187; called by muse, mutect2, varscan2
- MARCHF7 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.134); catalogued as COSV52031435; called by muse, mutect2, varscan2
- MARCO | c.1271T>C p.V424A | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV100503851; called by muse, mutect2, varscan2
- MAST1 | c.3010G>T p.E1004* | Nonsense Mutation (SNP) | VAF 18/164 reads (11%) | catalogued as COSV99263710; called by muse, varscan2
- MAST2 | c.4376C>T p.S1459F | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV100788774; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2
- MC1R | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100206083; called by muse, mutect2, varscan2
- MECP2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV100318513; called by muse, mutect2, varscan2
- MED1 | c.2449C>A p.Q817K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.761); catalogued as COSV100328167; called by muse, mutect2, varscan2
- MEGF8 | c.5795G>T p.S1932I (on ENST00000251268 / NM_001271938.2; = p.S1865I on NM_001410.3) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV99239053; called by muse, mutect2, varscan2
- METTL7B | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.653); catalogued as COSV99159404; called by muse, mutect2, varscan2
- MFSD2B | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.216); catalogued as rs762246600, COSV100601236; called by muse, mutect2
- MIB1 | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV99839476; called by muse, mutect2, varscan2
- MIEF1 | c.1348C>G p.L450V | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100307843, COSV100307906; called by muse, mutect2, varscan2
- MINDY2 | c.1066A>G p.I356V | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs1567055492, COSV100376601; called by muse, mutect2, varscan2
- MKI67 | c.3392C>G p.S1131C | Missense Mutation (SNP) | VAF 68/340 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs969082231, COSV100896993; called by muse, mutect2, varscan2
- MMP12 | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100405080; called by muse, mutect2, varscan2
- MMRN1 | c.2284C>A p.H762N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV99307770; called by muse, mutect2, varscan2
- MMRN2 | c.2714G>T p.G905V | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV100922666; called by muse, mutect2, varscan2
- MORF4L1 | c.517C>T p.R173W (on ENST00000331268 / NM_206839.2; = p.R134W on NM_006791.4) | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV100489221; called by muse, mutect2, varscan2
- MPEG1 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.737); catalogued as COSV99915947; called by muse, mutect2, varscan2
- MRPS15 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs200804313, COSV100118247; called by muse, mutect2, varscan2
- MRPS35 | c.702G>T p.W234C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99317271; called by muse, mutect2, varscan2
- MTMR1 | c.1833G>C p.Q611H | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100953163; called by muse, mutect2, varscan2
- MTMR6 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as COSV101110848; called by muse, mutect2, varscan2
- MTX3 | c.254C>G p.S85* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV101560521; called by muse, mutect2
- MUC16 | c.20632G>C p.E6878Q | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.685); catalogued as rs1481994108, COSV101201727; called by muse, mutect2
- MUC16 | c.8162C>A p.P2721Q | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV101201728; called by muse, mutect2, varscan2
- MUC2 | c.3418C>T p.R1140W | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs759575868; called by muse, mutect2, varscan2
- MUC4 | c.1844C>G p.S615* | Nonsense Mutation (SNP) | VAF 200/742 reads (27%) | catalogued as COSV100642283; called by muse, mutect2
- MUC5AC | c.1800C>A p.F600L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.04); catalogued as COSV100650702; called by muse, mutect2, varscan2
- MXI1 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99491546; called by muse, mutect2, varscan2
- MYCN | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1357629501, COSV99808551; called by muse, mutect2, varscan2
- MYH10 | c.4762G>A p.E1588K | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV99346378; called by muse, mutect2, varscan2
- MYH13 | c.2988G>C p.L996F | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV52837510, COSV99355472; called by muse, mutect2, varscan2
- MYNN | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); catalogued as rs1275228596, COSV100582347, COSV62992397; called by muse, mutect2
- NAALADL1 | c.904T>G p.L302V | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100368244; called by muse, mutect2, varscan2
- NCAPG2 | c.2427G>T p.K809N | Missense Mutation (SNP) | VAF 83/311 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV99317625; called by muse, mutect2, varscan2
- NCBP1 | c.955C>T p.H319Y | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV100912686; called by muse, mutect2, varscan2
- NCOA1 | c.3808C>G p.Q1270E | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV99947082; called by muse, mutect2, varscan2
- NDUFA10 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs771275102, COSV99401756; called by muse, mutect2, varscan2
- NDUFA12 | c.422C>G p.S141* | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as COSV100580900; called by muse, mutect2, varscan2
- NES | c.2085G>T p.E695D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV100957995; called by muse, mutect2, varscan2
- NFXL1 | c.1169G>C p.R390P | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100217042, COSV61198477; called by muse, mutect2, varscan2
- NHS | c.2240C>G p.S747* | Nonsense Mutation (SNP) | VAF 63/118 reads (53%) | catalogued as COSV101196991, COSV66278265; called by muse, mutect2, varscan2
- NID2 | c.3437G>A p.G1146E | Missense Mutation (SNP) | VAF 88/376 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99357275; called by muse, mutect2, varscan2
- NIN | c.4981G>A p.E1661K (on ENST00000382041 / NM_182946.1; = p.E948K on NM_016350.4) | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99815285; called by muse, varscan2
- NKX2-4 | c.784C>G p.L262V | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as rs777036252, COSV100698634; called by muse, mutect2, varscan2
- NLRP4 | c.1507C>G p.L503V | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.279); catalogued as COSV100016881; called by muse, mutect2, varscan2
- NMUR1 | c.940C>T p.H314Y | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100532166; called by muse, mutect2, varscan2
- NOP53 | c.116G>C p.R39P | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54409254, COSV99622239; called by muse, mutect2, varscan2
- NOP58 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV99970846; called by muse, mutect2, varscan2
- NOTCH1 | c.4474C>T p.Q1492* | Nonsense Mutation (SNP) | VAF 6/51 reads (12%) | catalogued as COSV99491764; called by muse, mutect2, varscan2
- NRAP | c.2770-1G>A p.X924_splice (on ENST00000359988 / NM_001322945.2; = p.X889_splice on NM_006175.4) | Splice Site (SNP) | VAF 26/107 reads (24%) | catalogued as COSV100748613; called by muse, mutect2, varscan2
- NRAP | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 55/293 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV100748614; called by muse, mutect2, varscan2
- NRP2 | c.1027G>T p.A343S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs555467484, COSV99783831, COSV99785676; called by muse, mutect2, varscan2
- NRXN1 | c.3221G>A p.G1074E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58446227, COSV58451619; called by muse, mutect2
- NRXN1 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1312769037, COSV101280653; called by muse, mutect2, varscan2
- NUDCD1 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as COSV99517726; called by muse, mutect2, varscan2
- NUDCD1 | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs757361524, COSV99517730; called by muse, mutect2, varscan2
- NUP35 | c.25C>G p.Q9E | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.217); catalogued as COSV54558702, COSV99717936; called by muse, mutect2
- NUP42 | c.216C>A p.S72R | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV99331171; called by muse, mutect2, varscan2
- OFD1 | c.2756G>T p.R919M | Missense Mutation (SNP) | VAF 110/212 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as COSV100366539; called by muse, mutect2, varscan2
- OLFM2 | c.690C>T p.V230= | Splice Region (SNP) | VAF 5/14 reads (36%) | catalogued as rs1383230939, COSV99322048; called by muse, mutect2, varscan2
- OOEP | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV64859079; called by muse, mutect2
- OR14K1 | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99315489; called by muse, mutect2, varscan2
- OR2B2 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV100308235, COSV57580039; called by muse, mutect2, varscan2
- OR4A5 | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.14); catalogued as rs1292170896, COSV100157304; called by muse, mutect2, varscan2
- OR51G1 | c.338A>C p.E113A | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100429439; called by muse, mutect2, varscan2
- OR52E8 | c.149C>A p.A50D | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs764919132, COSV101191058; called by muse, varscan2
- OR52N4 | c.766C>G p.P256A | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV100421763, COSV57890678; called by muse, mutect2, varscan2
- OR56A1 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as COSV100360552; called by muse, mutect2, varscan2
- OR5D18 | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 69/269 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100450902, COSV61737031; called by muse, mutect2, varscan2
- OR5M1 | c.289T>C p.C97R | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV101591611, COSV73201961; called by muse, mutect2, varscan2
- OR6B1 | c.824T>A p.F275Y | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101281673; called by muse, mutect2, varscan2
- OR8H1 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1400967234, COSV100477358; called by muse, mutect2, varscan2
- OSBPL3 | c.580C>G p.Q194E | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100514548, COSV57664000; called by muse, mutect2, varscan2
- OXR1 | c.277C>T p.Q93* (on ENST00000442977 / NM_001198532.1; = p.Q92* on NM_018002.3) | Nonsense Mutation (SNP) | VAF 7/96 reads (7%) | catalogued as COSV100367686; called by muse, mutect2
- PADI4 | c.391A>G p.R131G | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs780300532, COSV100966921; called by muse, mutect2, varscan2
- PANK4 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as rs760254092, COSV101022554, COSV65865614; called by muse, mutect2, varscan2
- PAX7 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100946975; called by muse, mutect2, varscan2
- PAXIP1 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV101250016; called by muse, mutect2
- PCDHB11 | c.2253C>A p.Y751* | Nonsense Mutation (SNP) | VAF 116/243 reads (48%) | catalogued as COSV61311544, COSV61314431; called by muse, mutect2, varscan2
- PCOLCE2 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV56000166, COSV99930940; called by muse, mutect2
- PDCD5 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs201933073, COSV55679153, COSV99694802; called by muse, mutect2
- PDZRN3 | c.1846G>T p.G616C | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.91); catalogued as COSV99732075; called by muse, mutect2, varscan2
- PER1 | c.2354T>A p.L785Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV100424855; called by muse, mutect2, varscan2
- PHACTR3 | c.1123G>C p.D375H | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.647); catalogued as COSV100733208, COSV63028501; called by muse, mutect2, varscan2
- PHB2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV54643605, COSV99781311; called by muse, mutect2
- PHC2 | c.1344C>G p.F448L | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.952); catalogued as rs1356933076, COSV57107629; called by muse, mutect2, varscan2
- PHTF2 | c.970C>G p.Q324E (on ENST00000248550 / NM_001366089.1; = p.Q286E on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as COSV99302342; called by muse, mutect2
- PI4KB | c.1228G>A p.D410N (on ENST00000368873 / NM_001369623.1; = p.D422N on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99650169; called by muse, mutect2, varscan2
- PIANP | c.827G>T p.R276L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100272404; called by muse, mutect2, varscan2
- PIEZO2 | c.7735A>T p.T2579S | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99555512; called by muse, mutect2, varscan2
- PIGZ | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as COSV53013867; called by muse, mutect2, varscan2
- PITPNM2 | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.991); catalogued as rs758849942, COSV99759658; called by muse, mutect2, varscan2
- PIWIL1 | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 20/82 reads (24%) | catalogued as rs754777604, COSV99806920; called by muse, mutect2, varscan2
- PKHD1L1 | c.4851T>A p.C1617* | Nonsense Mutation (SNP) | VAF 48/276 reads (17%) | catalogued as rs774498036, COSV101006835; called by muse, mutect2, varscan2
- PKP2 | c.1750G>T p.D584Y | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50750192, COSV99298488; called by muse, mutect2, varscan2
- PKP2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.722); catalogued as COSV50752737; called by muse, mutect2, varscan2
- PLCH1 | c.2857C>T p.Q953* (on ENST00000340059 / NM_001130960.2; = p.Q945* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/218 reads (6%) | catalogued as COSV100398241; called by muse, mutect2
- PLCXD3 | c.103+1G>A p.X35_splice | Splice Site (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100126404; called by muse, mutect2, varscan2
- PLCXD3 | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100126406; called by muse, mutect2, varscan2
- PLEKHB2 | c.544C>T p.Q182* (on ENST00000409279; = p.Q181* on NM_017958.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 76/225 reads (34%) | catalogued as COSV99301862; called by muse, mutect2, varscan2
- PLEKHG3 | c.141G>C p.K47N | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV55984151, COSV99907138; called by muse, mutect2, varscan2
- PLEKHO1 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.647); catalogued as COSV99215409; called by muse, mutect2, varscan2
- PNN | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 65/339 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as rs1169955754, COSV53768050; called by muse, mutect2, varscan2
- POLR3C | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV100493109; called by muse, mutect2, varscan2
- POLRMT | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV101648689; called by muse, mutect2, varscan2
- POP1 | c.2302G>C p.E768Q | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as COSV100856112; called by muse, mutect2, varscan2
- POTEM | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1215463995, COSV66936010; called by mutect2, varscan2
- PPFIA3 | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV100495287; called by muse, mutect2, varscan2
- PPIG | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99644171, COSV99644943; called by muse, mutect2, varscan2
- PPP1R11 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs957360927, COSV99748746; called by muse, mutect2, varscan2
- PRAMEF4 | c.1129A>T p.S377C | Missense Mutation (SNP) | VAF 57/453 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV99340237; called by muse, mutect2, varscan2
- PRDM15 | c.2314G>C p.E772Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV99520993; called by muse, mutect2, varscan2
- PREX2 | c.3702G>C p.Q1234H | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV55799959, COSV99905404, COSV99909969; called by muse, mutect2, varscan2
- PRKDC | c.5432G>T p.R1811L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100042878, COSV58053845; called by muse, mutect2
- PRPF39 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as COSV100866045; called by muse, mutect2
- PRPH | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.167); catalogued as COSV99142076; called by muse, mutect2, varscan2
- PRSS36 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs1191602566, COSV99191333; called by muse, mutect2, varscan2
- PRUNE2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as rs745462357, COSV100943317; called by muse, mutect2, varscan2
- PSD | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99193964; called by muse, mutect2, varscan2
- PSD2 | c.1788G>C p.K596N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99217489; called by muse, mutect2, varscan2
- PTPN4 | c.1906G>T p.D636Y | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as COSV99751410; called by muse, mutect2, varscan2
- PTPRA | c.191C>T p.T64I | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.04); catalogued as COSV99400634; called by muse, mutect2, varscan2
- PTPRN2 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 20/92 reads (22%) | catalogued as COSV101235357; called by mutect2, varscan2
- PTPRO | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.785); catalogued as COSV99841748; called by muse, mutect2, varscan2
- PTPRT | c.4111G>T p.E1371* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as COSV100630487, COSV61969681; called by muse, mutect2, varscan2
- PTRH1 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100077090; called by muse, mutect2, varscan2
- PYHIN1 | c.863C>G p.S288C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.432); catalogued as COSV100932417; called by muse, mutect2, varscan2
- R3HDM2 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 61/344 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.093); catalogued as COSV100715600; called by muse, mutect2, varscan2
- RAB19 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52045114; called by muse, mutect2
- RAD50 | c.18G>C p.K6N | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99529661; called by muse, mutect2, varscan2
- RANBP2 | c.4585A>T p.S1529C | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as COSV99313269; called by muse, mutect2, varscan2
- RANBP6 | c.114G>C p.E38D | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV99424420; called by muse, mutect2, varscan2
- RBM14 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs764529837, COSV59558058; called by muse, mutect2, varscan2
- RBM8A | c.39A>T p.E13D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV100355402; called by muse, mutect2, varscan2
- RICTOR | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.699); catalogued as COSV99705747; called by muse, mutect2
- RILPL2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.162); catalogued as COSV99760306; called by muse, mutect2
- RIOX1 | c.931T>G p.F311V | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.055); catalogued as COSV100408119; called by muse, mutect2, varscan2
- RIPK1 | c.1692C>G p.F564L | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99454927; called by muse, mutect2, varscan2
- RND2 | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV99870090; called by muse, mutect2, varscan2
- ROBO2 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV100164581, COSV100169949; called by muse, mutect2, varscan2
- RP1L1 | c.4682A>T p.Q1561L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV101223634; called by muse, mutect2, varscan2
- RPS25 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100548920; called by muse, mutect2, varscan2
- RPS6KA6 | c.1456G>C p.V486L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV99425463; called by muse, mutect2
- RTL8B | c.137A>C p.Q46P | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101195651; called by muse, mutect2, varscan2
- RTN2 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 86/167 reads (51%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV99839270; called by muse, mutect2, varscan2
- RYR3 | c.2174C>A p.P725H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV101214598; called by muse, mutect2, varscan2
- SAFB | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV99413186; called by muse, mutect2
- SARS1 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV52319800; called by muse, mutect2, varscan2
- SCN11A | c.3262G>C p.E1088Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100182562, COSV56565569; called by muse, mutect2, varscan2
- SCN1A | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV57663707; called by muse, mutect2, varscan2
- SCN2A | c.3227G>A p.S1076N | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.808); catalogued as COSV99333518; called by muse, mutect2, varscan2
- SEC61A1 | c.715C>T p.L239F | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99685030; called by muse, mutect2, varscan2
- SEMA3F | c.1789C>T p.Q597* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV99137967; called by muse, mutect2, varscan2
- SEMA6D | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.798); catalogued as COSV100317636; called by muse, mutect2, varscan2
- SERPINA5 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61574723; called by muse, varscan2
- SERPINI2 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV52987417; called by muse, mutect2
- SETD2 | c.5250G>C p.Q1750H | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV57437239; called by muse, mutect2
- SGK1 | c.1129-1G>A p.X377_splice | Splice Site (SNP) | VAF 14/98 reads (14%) | catalogued as COSV99397989; called by muse, mutect2, varscan2
- SH3BP2 | c.1205T>A p.L402Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.975); catalogued as COSV100697043; called by muse, mutect2, varscan2
- SH3BP4 | c.1011C>G p.I337M | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100749315; called by muse, mutect2
- SHARPIN | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV100010617; called by muse, varscan2
- SHARPIN | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.588); catalogued as rs762859512, COSV100010618; called by muse, mutect2, varscan2
- SHC1 | c.803C>T p.P268L (on ENST00000368445 / NM_183001.5; = p.P158L on NM_003029.5) | Missense Mutation (SNP) | VAF 123/522 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as rs1486973471, COSV63534645; called by muse, mutect2, varscan2
- SHC1 | c.802C>T p.P268S (on ENST00000368445 / NM_183001.5; = p.P158S on NM_003029.5) | Missense Mutation (SNP) | VAF 124/524 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV100821162; called by muse, mutect2, varscan2
- SIPA1L2 | c.3790G>A p.D1264N | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs532670311, COSV53393284; called by muse, mutect2, varscan2
- SKIL | c.584C>G p.S195* | Nonsense Mutation (SNP) | VAF 10/221 reads (5%) | catalogued as COSV52063647; called by muse, mutect2
- SLC11A1 | c.578G>C p.R193P | Missense Mutation (SNP) | VAF 58/413 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51916344, COSV99262478; called by muse, mutect2, varscan2
- SLC26A11 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV100413605, COSV58339983; called by muse, mutect2, varscan2
- SLC37A3 | c.906G>C p.L302F | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100405714; called by muse, mutect2, varscan2
- SLC38A9 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100591263, COSV100591582; called by muse, mutect2, varscan2
- SLC39A3 | c.363C>G p.F121L | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.193); catalogued as rs753648505, COSV99514312; called by muse, mutect2, varscan2
- SLC5A9 | c.2033G>A p.G678D | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99361992; called by muse, mutect2, varscan2
- SLC7A2 | c.637G>A p.G213R (on ENST00000494857 / NM_001370338.1; = p.G253R on NM_003046.6) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99135939; called by muse, varscan2
- SLC7A2 | c.661A>G p.S221G (on ENST00000494857 / NM_001370338.1; = p.S261G on NM_003046.6) | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV99135944; called by muse, varscan2
- SLX4IP | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 14/130 reads (11%) | catalogued as rs773283085, COSV100570674, COSV100570869, COSV57950476; called by muse, mutect2, varscan2
- SMG1 | c.1087C>G p.Q363E | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV101246848; called by muse, mutect2, varscan2
- SMG8 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99959075; called by muse, mutect2, varscan2
- SNAP23 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.36); catalogued as rs1323180650, COSV99987478; called by muse, mutect2, varscan2
- SNX31 | c.1139T>C p.M380T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61262640; called by muse, mutect2, varscan2
- SOGA3 | c.2254G>A p.D752N | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64106236; called by muse, mutect2, varscan2
- SORL1 | c.446C>G p.S149* | Nonsense Mutation (SNP) | VAF 5/72 reads (7%) | catalogued as COSV52755640, COSV99494747; called by muse, mutect2
- SOX13 | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99690056; called by muse, mutect2, varscan2
- SP140 | c.12G>T p.Q4H | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.041); catalogued as COSV100614087; called by muse, mutect2, varscan2
- SPATC1 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV101085323; called by mutect2, varscan2
- SPECC1L | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV100063256; called by muse, mutect2, varscan2
- SPEF2 | c.478C>G p.Q160E | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as COSV99214854; called by muse, mutect2
- SPG11 | c.4309G>A p.E1437K | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV99969656; called by muse, mutect2, varscan2
- SPG11 | c.4108G>A p.D1370N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); catalogued as COSV55990584; called by muse, mutect2, varscan2
- SPG11 | c.3856G>C p.E1286Q | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); catalogued as COSV56001950, COSV99969660; called by muse, mutect2, varscan2
- SPHKAP | c.135G>C p.K45N | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100764534; called by muse, mutect2, varscan2
- SPIN1 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101021080, COSV101021120, COSV65499806; called by muse, mutect2, varscan2
- SPOCK1 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs149415518; called by muse, mutect2, varscan2
- SPR | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99318105; called by muse, mutect2, varscan2
- SPRR3 | c.320C>A p.T107N | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.969); catalogued as COSV54879791; called by muse, varscan2
- SPTBN2 | c.3197G>A p.R1066Q | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.094); catalogued as rs527626787, COSV59453876; called by mutect2, varscan2
- SRGAP1 | c.3046G>T p.A1016S | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV100755145; called by muse, mutect2, varscan2
- SSB | c.612A>C p.K204N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99641909; called by muse, mutect2, varscan2
- STAB2 | c.4139G>T p.G1380V | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101186309, COSV66338602; called by muse, mutect2, varscan2
- STEAP2 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV99840702; called by muse, mutect2, varscan2
- STXBP1 | c.1228C>T p.L410F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100964636; called by mutect2, varscan2
- SUGP1 | c.893T>C p.L298P | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99895581; called by muse, mutect2, varscan2
- SUPV3L1 | c.2241G>C p.M747I | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV100669893; called by muse, mutect2, varscan2
- SVEP1 | c.4285G>C p.D1429H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV100239091, COSV57048202; called by muse, mutect2
- SYNCRIP | c.609A>C p.R203S | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100784331; called by muse, mutect2, varscan2
- SZT2 | c.8544T>A p.H2848Q (on ENST00000634258 / NM_001365999.1; = p.H2791Q on NM_015284.4) | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100987675; called by muse, mutect2, varscan2
- TAF1L | c.3403C>T p.Q1135* | Nonsense Mutation (SNP) | VAF 87/184 reads (47%) | catalogued as COSV54261735, COSV54264219; called by muse, mutect2, varscan2
- TARS1 | c.1077C>G p.F359L | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.168); catalogued as COSV99466473; called by muse, mutect2
- TAS1R2 | c.1052G>A p.S351N | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64745090; called by muse, mutect2, varscan2
- TBC1D31 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV99783233; called by muse, mutect2, varscan2
- TBC1D32 | c.1783G>T p.E595* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99251303; called by muse, mutect2, varscan2
- TEAD2 | c.261C>G p.I87M | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99678805; called by muse, varscan2
- TECPR1 | c.3394G>A p.D1132N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as rs1318424975, COSV100011981; called by muse, mutect2
- TG | c.4852G>A p.V1618M | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as rs114101452; called by muse, mutect2, varscan2
- TGM7 | c.2101G>A p.D701N | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.953); catalogued as COSV101476901; called by muse, mutect2, varscan2
- TGOLN2 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 62/347 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); catalogued as COSV99965130; called by muse, mutect2, varscan2
- THOP1 | c.487-1G>A p.X163_splice | Splice Site (SNP) | VAF 27/70 reads (39%) | catalogued as rs1439807338, COSV100310788; called by muse, mutect2, varscan2
- TIMM22 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.113); catalogued as COSV100215876; called by muse, mutect2, varscan2
- TKTL2 | c.1476G>C p.E492D | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV54917486, COSV99761744; called by muse, mutect2, varscan2
- TLN2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100169268, COSV60891066; called by muse, mutect2, varscan2
- TMC7 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 18/135 reads (13%) | catalogued as COSV100432825; called by muse, mutect2, varscan2
- TMEM132E | c.2258G>T p.G753V (on ENST00000321639; = p.G843V on NM_001304438.2) | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.324); catalogued as COSV100396803; called by muse, mutect2, varscan2
- TMEM145 | c.155C>G p.S52W | Missense Mutation (SNP) | VAF 87/149 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100004130; called by muse, mutect2, varscan2
- TMTC3 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV99898696; called by muse, mutect2, varscan2
- TPP1 | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.234); catalogued as COSV100196640; called by muse, mutect2, varscan2
- TPR | c.6562C>G p.Q2188E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV100824251, COSV66602122; called by muse, mutect2
- TPX2 | c.854C>G p.S285C | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV100302094; called by muse, mutect2, varscan2
- TRABD | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100326955; called by muse, mutect2, varscan2
- TRPS1 | c.661G>T p.D221Y (on ENST00000220888 / NM_001330599.2; = p.D234Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99634430; called by muse, mutect2, varscan2
- TRRAP | c.8560G>C p.E2854Q (on ENST00000359863 / NM_001244580.1; = p.E2836Q on NM_003496.3) | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs1474998297, COSV100722977; called by muse, mutect2, varscan2
- TSGA10 | c.306G>C p.E102D | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61823704; called by muse, mutect2, varscan2
- TSHZ3 | c.1163G>A p.C388Y | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV99552752; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 48/141 reads (34%) | catalogued as COSV99535347; called by muse, mutect2, varscan2
- TSPOAP1 | c.3098C>T p.S1033L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99272741; called by muse, mutect2
- TTC39A | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV52957608, COSV99397107; called by muse, mutect2, varscan2
- TTC9B | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as rs774871244, COSV99454859; called by muse, mutect2, varscan2
- TTN | c.85919G>T p.R28640I (on ENST00000591111; = p.R21216I on NM_003319.4) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | PolyPhen possibly damaging (0.885); catalogued as COSV59899929; called by muse, mutect2, varscan2
- TTN | c.16039C>A p.P5347T (on ENST00000591111; = p.P4420T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/132 reads (21%) | PolyPhen benign (0.011); catalogued as COSV100630206; called by muse, mutect2, varscan2
- TXNDC16 | c.1313-1G>A p.X438_splice | Splice Site (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99909662; called by muse, mutect2, varscan2
- TYMP | c.158A>G p.D53G | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV52687643; called by muse, mutect2, varscan2
- TYMS | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 78/606 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100025836; called by muse, mutect2, varscan2
- UBA6 | c.850C>G p.H284D | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as COSV100451895; called by muse, mutect2, varscan2
- UGT1A9 | c.572C>A p.P191H | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100693219, COSV60844523; called by muse, mutect2, varscan2
- ULK2 | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100860985; called by mutect2, varscan2
- UNC13B | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV65934606; called by muse, mutect2
- UPF2 | c.2713G>T p.G905C | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV100707456; called by muse, mutect2, varscan2
- USF3 | c.2290G>C p.D764H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV100325809; called by muse, mutect2, varscan2
- USH2A | c.6523C>A p.R2175S | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.687); catalogued as COSV100242695, COSV56389913; called by muse, mutect2
- USO1 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV99363175; called by muse, mutect2, varscan2
- USP17L2 | c.516G>T p.M172I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV100414743; called by muse, mutect2, varscan2
- USP24 | c.7100G>A p.R2367Q | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs778463727, COSV99600943; called by muse, mutect2, varscan2
- USP43 | c.1639C>T p.Q547* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99557067; called by muse, mutect2
- USP48 | c.842G>C p.R281T | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100380257; called by muse, mutect2, varscan2
- VENTX | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV100384146; called by muse, mutect2, varscan2
- VPS13A | c.9130G>A p.E3044K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100653531; called by muse, mutect2, varscan2
- VPS53 | c.1708G>A p.E570K (on ENST00000571805 / NM_001366253.2; = p.E541K on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV99346704; called by muse, mutect2, varscan2
- VPS9D1 | c.1564G>C p.E522Q | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV101232044; called by muse, mutect2
- VSTM2A | c.272C>A p.P91Q | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.853); catalogued as COSV100173372; called by muse, mutect2, varscan2
- WDR20 | c.1288C>A p.P430T | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV100085479, COSV54473636; called by muse, mutect2, varscan2
- WDR62 | c.2398G>A p.D800N | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV99544241; called by muse, mutect2, varscan2
- XKR4 | c.1292T>A p.I431N | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100534025; called by muse, mutect2, varscan2
- ZAN | c.7074C>G p.I2358M | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as COSV100770343; called by muse, mutect2
- ZCWPW2 | c.811A>C p.K271Q | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV101075305; called by muse, mutect2, varscan2
- ZEB2 | c.3313G>A p.E1105K | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs769219699, COSV57965949; called by muse, mutect2, varscan2
- ZKSCAN2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as COSV100048555; called by muse, mutect2
- ZKSCAN5 | c.451G>C p.A151P | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV100460376, COSV58743696; called by muse, mutect2, varscan2
- ZNF136 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.132); catalogued as rs147268850; called by muse, mutect2
- ZNF136 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV100678023, COSV100678155; called by muse, mutect2, varscan2
- ZNF146 | c.75C>G p.F25L | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100757774; called by muse, mutect2
- ZNF146 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 23/315 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV61931331, COSV61931416; called by muse, mutect2
- ZNF174 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 21/498 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1341234345, COSV99237731; called by muse, mutect2
- ZNF184 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 86/165 reads (52%) | catalogued as COSV99280080; called by muse, mutect2, varscan2
- ZNF365 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as COSV101237996; called by muse, mutect2, varscan2
- ZNF460 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV64415716; called by muse, mutect2, varscan2
- ZNF527 | c.1469G>C p.R490T | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV100648781; called by muse, mutect2
- ZNF532 | c.3028C>T p.P1010S | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV100267168; called by muse, mutect2, varscan2
- ZNF568 | c.1381C>A p.L461I | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV100451206; called by muse, mutect2
- ZNF585B | c.435C>G p.F145L | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100459653; called by muse, mutect2
- ZNF714 | c.1416C>G p.N472K | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775538323, COSV99395586; called by muse, mutect2
- ZNF721 | c.424C>T p.Q142* (on ENST00000338977; = p.Q154* on NM_133474.4) | Nonsense Mutation (SNP) | VAF 9/106 reads (8%) | catalogued as COSV100167829; called by muse, mutect2
- ZNF778 | c.2176G>C p.E726Q | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV100124632; called by muse, mutect2
- ZNF799 | c.557G>A p.R186K | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.784); catalogued as COSV101345297; called by muse, mutect2, varscan2
- ZNF804B | c.1473C>A p.D491E | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100306225; called by muse, mutect2, varscan2
- ZNF804B | c.1474C>T p.H492Y | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as COSV60862467; called by muse, mutect2, varscan2
- ZNF99 | c.1078G>C p.E360Q | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV101233970; called by muse, mutect2
- ZSCAN21 | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV99461287; called by muse, mutect2, varscan2
- ARPC2 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 4/89 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2
- CHD1L | c.1765_1783del p.R589Wfs*2 | Frame Shift Del (DEL) | VAF 27/126 reads (21%) | called by mutect2, pindel, varscan2
- DNAH11 | c.5661G>C p.M1887I | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- EEF1AKMT2 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGHV3-21 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 49/239 reads (21%) | called by muse, varscan2
- LRRC37A3 | c.2189A>T p.K730I | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- MTMR4 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MUC2 | c.2586C>G p.F862L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (1); called by muse, mutect2
- OR52E8 | c.107del p.P36Lfs*19 | Frame Shift Del (DEL) | VAF 44/191 reads (23%) | called by pindel, varscan2
- OR6C4 | c.112del p.L38* | Frame Shift Del (DEL) | VAF 88/240 reads (37%) | called by mutect2, pindel*, varscan2
- P2RX1 | c.1098G>C p.K366N | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); called by muse, mutect2
- PHF3 | c.2681-2_2681delinsTT p.X894_splice | Splice Site (DEL) | VAF 43/88 reads (49%) | called by pindel, varscan2*
- PLEKHG5 | c.-53-13_-41del | Splice Site (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- PLSCR1 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 8/232 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- PRAMEF19 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- SCP2D1 | c.359del p.L120Wfs*4 | Frame Shift Del (DEL) | VAF 28/117 reads (24%) | called by mutect2, pindel, varscan2
- SIX5 | c.2071del p.H691Tfs*4 | Frame Shift Del (DEL) | VAF 32/80 reads (40%) | called by pindel, varscan2
- SIX5 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.337); called by muse, varscan2
- SKP2 | c.375G>C p.K125N | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2
- SMG1 | c.7595_7604+8delinsAAC p.X2532_splice | Splice Site (DEL) | VAF 38/168 reads (23%) | called by pindel, varscan2*
- SPTBN2 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- TEX13A | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.712); called by muse, mutect2
- TEX26 | c.646+3_646+6del p.X216_splice | Splice Site (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel
- ZNF260 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 16/456 reads (4%) | SIFT tolerated (0.82); PolyPhen benign (0.118); called by muse, mutect2
- ABCA1 | c.1812C>T p.I604= | Silent (SNP) | VAF 7/183 reads (4%) | called by muse, mutect2
- ABCA9 | c.4056G>A p.L1352= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100383494; called by muse, mutect2, varscan2
- ACADVL | c.825G>A p.V275= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as rs777031338, COSV99138875; called by muse, mutect2, varscan2
- ADAM19 | c.2130C>A p.A710= | Silent (SNP) | VAF 34/165 reads (21%) | catalogued as COSV57423416, COSV99978479; called by muse, mutect2, varscan2
- ADCY9 | c.2136C>G p.L712= | Silent (SNP) | VAF 13/145 reads (9%) | catalogued as COSV99570888; called by muse, mutect2
- ADGRA1 | c.348C>A p.A116= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV101192746; called by mutect2, varscan2
- ADGRV1 | c.13515C>T p.I4505= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV101316510; called by muse, mutect2
- AGAP1 | c.963G>C p.R321= | Silent (SNP) | VAF 19/143 reads (13%) | catalogued as COSV100367100; called by muse, mutect2, varscan2
- ALDH18A1 | c.1437C>T p.I479= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100973297; called by muse, mutect2, varscan2
- ANKMY1 | c.918C>T p.N306= | Silent (SNP) | VAF 34/137 reads (25%) | catalogued as rs201176859, COSV99803217; called by muse, mutect2, varscan2
- ANKRD11 | c.3354C>A p.I1118= | Silent (SNP) | VAF 35/223 reads (16%) | catalogued as COSV56363025, COSV99970624; called by muse, mutect2, varscan2
- ANKRD12 | c.3204G>A p.K1068= | Silent (SNP) | VAF 33/212 reads (16%) | catalogued as COSV100042101, COSV50844272; called by muse, mutect2, varscan2
- AP2M1 | c.954G>A p.Q318= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99490947; called by muse, mutect2
- ARHGAP35 | c.4413G>A p.P1471= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs201125011, COSV101351703; called by muse, mutect2, varscan2
- ARMC4 | c.1728G>A p.G576= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1198624354, COSV100537420; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATG9B | c.1602C>T p.F534= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99872164; called by muse, mutect2, varscan2
- ATOH8 | c.78C>G p.L26= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV60402417; called by muse, mutect2, varscan2
- AWAT2 | c.897C>A p.I299= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as rs1410400116, COSV52143766, COSV99339792; called by muse, mutect2, varscan2
- BMI1 | c.579C>T p.V193= | Silent (SNP) | VAF 57/205 reads (28%) | catalogued as COSV100936502; called by muse, mutect2, varscan2
- BNC2 | c.204G>A p.L68= | Silent (SNP) | VAF 144/213 reads (68%) | catalogued as COSV101034461; called by muse, mutect2, varscan2
- C15orf39 | c.556C>T p.L186= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100641473, COSV62298524; called by muse, mutect2
- C15orf39 | c.3018C>T p.F1006= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV100641474; called by muse, mutect2, varscan2
- C1orf109 | c.19C>T p.L7= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV100523791; called by muse, mutect2
- CACNA1C | c.6027C>A p.L2009= (on ENST00000399634 / NM_001167625.1; = p.L1938= on NM_000719.7) | Silent (SNP) | VAF 56/161 reads (35%) | catalogued as COSV100222269, COSV59782639; called by muse, mutect2, varscan2
- CACNA1S | c.483C>A p.V161= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV100755382; called by muse, mutect2
- CBX5 | c.453T>A p.V151= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV99267878; called by muse, mutect2
- CD1E | c.933C>A p.I311= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100937066; called by muse, mutect2, varscan2
- CD22 | c.1581C>T p.L527= | Silent (SNP) | VAF 14/204 reads (7%) | catalogued as rs1468274551, COSV99323766; called by muse, mutect2
- CDC42BPB | c.4680C>T p.V1560= | Silent (SNP) | VAF 36/266 reads (14%) | catalogued as COSV100775616; called by muse, mutect2, varscan2
- CDH9 | c.2202G>C p.S734= | Silent (SNP) | VAF 48/168 reads (29%) | catalogued as COSV99154539; called by muse, mutect2, varscan2
- CERKL | c.1393C>A p.R465= (on ENST00000339098 / NM_001030311.2; = p.R439= on NM_201548.5) | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV100184198, COSV59204341; called by muse, mutect2, varscan2
- CHD7 | c.6411A>T p.A2137= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV101418452; called by muse, mutect2, varscan2
- CHD8 | c.5661C>G p.L1887= (on ENST00000646647 / NM_001170629.2; = p.L1608= on NM_020920.4) | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as rs746231563, COSV100765378; called by muse, mutect2, varscan2
- CHRNE | c.702C>T p.L234= | Silent (SNP) | VAF 24/180 reads (13%) | catalogued as rs1344473749, COSV99545374; called by muse, mutect2, varscan2
- CHST6 | c.558G>A p.P186= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as rs1298173365, COSV100178575; called by muse, mutect2, varscan2
- CNTNAP4 | c.1435C>T p.L479= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV100273375; called by muse, mutect2
- COX6B1 | c.18G>A p.E6= | Silent (SNP) | VAF 31/271 reads (11%) | catalogued as rs555965567, COSV99876997; called by muse, mutect2, varscan2
- CPNE2 | c.741C>G p.T247= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV99321662; called by muse, mutect2, varscan2
- CPNE9 | c.1311T>C p.S437= | Silent (SNP) | VAF 51/109 reads (47%) | catalogued as rs1372973296, COSV99808474; called by muse, mutect2, varscan2
- CREBBP | c.6963C>G p.L2321= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as COSV99272033; called by muse, mutect2, varscan2
- CRYZ | c.594C>T p.F198= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100558717; called by muse, mutect2, varscan2
- CYP2C8 | c.942G>T p.L314= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV100988023; called by muse, mutect2, varscan2
- CYP2E1 | c.786C>T p.P262= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV99428911, COSV99429239; called by muse, mutect2, varscan2
- DAB2IP | c.2082G>T p.L694= (on ENST00000408936; = p.L666= on NM_032552.3) | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV99406331; called by muse, mutect2, varscan2
- DCHS1 | c.6741G>A p.L2247= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs1379361709, COSV100202600; called by muse, mutect2, varscan2
- DDX39B | c.844C>T p.L282= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV100795254, COSV100795281; called by muse, mutect2, varscan2
- DHX38 | c.1626C>G p.L542= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV99194588; called by muse, mutect2, varscan2
- DNAH11 | c.2388G>T p.L796= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV100180888; called by muse, mutect2, varscan2
- DNAH9 | c.11595T>A p.A3865= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as COSV99308151; called by muse, mutect2, varscan2
- DOCK11 | c.282G>A p.K94= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs1186302185, COSV99354742; called by muse, mutect2, varscan2
- DPP9 | c.855G>A p.V285= (on ENST00000598800; = p.V314= on NM_139159.5) | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV99506510; called by muse, mutect2, varscan2
- DSG2 | c.2115C>T p.V705= | Silent (SNP) | VAF 71/138 reads (51%) | catalogued as COSV99853558; called by muse, mutect2, varscan2
- DUSP29 | c.363C>A p.L121= | Silent (SNP) | VAF 38/140 reads (27%) | catalogued as COSV100633409; called by muse, mutect2, varscan2
- DYNC1I1 | c.1542C>G p.V514= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV100269284; called by muse, mutect2, varscan2
- ENPP7 | c.1180C>T p.L394= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs1555823782, COSV100093702; called by muse, mutect2, varscan2
- ENY2 | c.99G>T p.L33= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as rs1284294452, COSV99516796; called by muse, mutect2
- EPB41L3 | c.2184G>C p.L728= | Silent (SNP) | VAF 17/156 reads (11%) | catalogued as rs1484674755, COSV100550256; called by muse, mutect2, varscan2
- ESRP2 | c.1533C>G p.L511= (on ENST00000565858 / NM_001365264.1; = p.L501= on NM_024939.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as COSV99251493; called by muse, mutect2, varscan2
- ETNK2 | c.765C>T p.I255= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV100916624; called by muse, mutect2, varscan2
- EXOC3L2 | c.1755G>A p.L585= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99374644; called by muse, mutect2, varscan2
- FAH | c.48C>T p.N16= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as rs1256559961, COSV99930559; called by muse, mutect2
- FAM111A | c.1206C>T p.T402= | Silent (SNP) | VAF 56/236 reads (24%) | catalogued as COSV100659455; called by muse, mutect2, varscan2
- FAT4 | c.10338C>T p.I3446= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as COSV58679356; called by muse, mutect2, varscan2
- FCGBP | c.8430C>T p.C2810= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs1394423315; called by mutect2, varscan2
- FCGR2A | c.474G>A p.Q158= (on ENST00000271450 / NM_001136219.3; = p.Q157= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as COSV99615737; called by muse, mutect2, varscan2
- FCSK | c.36C>T p.I12= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV99851286; called by muse, mutect2, varscan2
- GAP43 | c.459C>A p.S153= | Silent (SNP) | VAF 41/81 reads (51%) | catalogued as COSV100525953; called by muse, mutect2, varscan2
- GAS1 | c.834G>C p.A278= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100075793, COSV53927450; called by muse, mutect2, varscan2
- GATA3 | c.715C>T p.L239= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV100651245; called by muse, mutect2, varscan2
- GBP3 | c.1299C>G p.L433= | Silent (SNP) | VAF 98/171 reads (57%) | catalogued as COSV99352749; called by muse, mutect2, varscan2
- GCC2 | c.4815G>A p.R1605= | Silent (SNP) | VAF 10/73 reads (14%) | called by mutect2, varscan2
- GDAP2 | c.1383G>C p.L461= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV101032171; called by muse, mutect2, varscan2
- GJA1 | c.696C>T p.F232= | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as COSV99247323; called by muse, mutect2, varscan2
- GJB7 | c.105C>G p.V35= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV51530776, COSV51531492, COSV99738764; called by muse, mutect2, varscan2
- GLP1R | c.1005G>C p.L335= | Silent (SNP) | VAF 47/171 reads (27%) | catalogued as COSV100952743; called by muse, mutect2, varscan2
- GLRX2 | c.477G>A p.K159= (on ENST00000367439 / NM_197962.3; = p.K160= on NM_016066.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100814233; called by muse, mutect2, varscan2
- GRB7 | c.1263C>T p.L421= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as rs962924990, COSV100485654; called by muse, varscan2
- GTF3C4 | c.2136C>G p.L712= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as COSV100936089; called by muse, mutect2, varscan2
- GUK1 | c.234G>A p.G78= | Silent (SNP) | VAF 7/142 reads (5%) | catalogued as COSV100451747; called by muse, mutect2
- GUSB | c.1755C>T p.L585= | Silent (SNP) | VAF 15/160 reads (9%) | catalogued as COSV100512770; called by muse, mutect2, varscan2
- GUSB | c.459C>T p.I153= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100512774; called by muse, mutect2, varscan2
- H2BC9 | c.69G>A p.Q23= | Silent (SNP) | VAF 50/153 reads (33%) | catalogued as COSV55099778, COSV55099825; called by muse, mutect2, varscan2
- HEXIM2 | c.492C>T p.I164= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs146054495; called by muse, mutect2, varscan2
- HKDC1 | c.2343C>T p.F781= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs148312270; called by muse, mutect2, varscan2
- IFT74 | c.1737G>C p.V579= | Silent (SNP) | VAF 112/142 reads (79%) | catalogued as COSV101197218; called by muse, mutect2, varscan2
- IRAK2 | c.249C>G p.L83= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV99844338; called by muse, mutect2, varscan2
- ITSN1 | c.3564G>A p.E1188= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as COSV101180624; called by muse, mutect2, varscan2
- KCNK16 | c.757C>T p.L253= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV100949322; called by muse, mutect2, varscan2
- KCNQ3 | c.171C>T p.L57= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs758097251, COSV101196443; called by muse, mutect2, varscan2
- KIAA1549L | c.2706G>C p.L902= (on ENST00000321505; = p.L1199= on NM_012194.3) | Silent (SNP) | VAF 66/188 reads (35%) | catalogued as rs759371096, COSV99684444; called by muse, mutect2, varscan2
- KIF9 | c.1173G>A p.Q391= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV99647027; called by muse, mutect2, varscan2
- KIRREL2 | c.879C>T p.V293= | Silent (SNP) | VAF 32/404 reads (8%) | catalogued as rs1295361029, COSV99384449; called by muse, mutect2
- KRT85 | c.102C>T p.I34= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs1299697011, COSV99225167; called by muse, mutect2, varscan2
- L2HGDH | c.498G>A p.L166= | Silent (SNP) | VAF 13/151 reads (9%) | catalogued as COSV99910563; called by muse, mutect2
- LAMA5 | c.1698C>T p.F566= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs758524258, COSV53374828; called by muse, mutect2, varscan2
- LRIT2 | c.369C>T p.F123= | Silent (SNP) | VAF 31/206 reads (15%) | catalogued as COSV100928353; called by muse, mutect2, varscan2
- LRP4 | c.5196C>T p.L1732= | Silent (SNP) | VAF 51/214 reads (24%) | catalogued as COSV101066891; called by muse, mutect2, varscan2
- LRRTM4 | c.420C>G p.L140= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as rs1558782117, COSV101297744; called by muse, mutect2
- MAGI3 | c.1044A>T p.I348= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as COSV100287911, COSV100290436; called by muse, mutect2, varscan2
- MAP1A | c.4722G>A p.E1574= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV100289233; called by muse, mutect2, varscan2
- MAP2K7 | c.828G>C p.R276= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV101208980, COSV101209145; called by muse, mutect2, varscan2
- MAP3K14 | c.69C>G p.P23= | Silent (SNP) | VAF 56/97 reads (58%) | catalogued as COSV100766562, COSV100766584; called by muse, mutect2, varscan2
- MARCHF4 | c.720C>G p.A240= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as COSV56107705, COSV99814809; called by muse, mutect2, varscan2
- MEGF10 | c.351C>T p.R117= | Silent (SNP) | VAF 43/78 reads (55%) | catalogued as COSV99175663; called by muse, mutect2, varscan2
- MGAT5B | c.603C>T p.L201= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV100048952; called by muse, mutect2, varscan2
- MIA3 | c.5061G>A p.V1687= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100484764; called by muse, mutect2, varscan2
- MKI67 | c.3588G>A p.Q1196= | Silent (SNP) | VAF 17/153 reads (11%) | catalogued as COSV100896816; called by muse, mutect2, varscan2
- MUC17 | c.9879G>T p.V3293= | Silent (SNP) | VAF 78/557 reads (14%) | catalogued as COSV100075053, COSV60307210; called by muse, mutect2, varscan2
- MYH4 | c.3091C>T p.L1031= | Silent (SNP) | VAF 132/265 reads (50%) | catalogued as rs140849469, COSV99702247; called by muse, mutect2, varscan2
- NCAPD2 | c.1282C>T p.L428= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV100217446; called by muse, mutect2, varscan2
- NCOA2 | c.4248G>T p.V1416= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV99145033; called by muse, mutect2, varscan2
- NEK5 | c.2126G>A p.*709= | Silent (SNP) | VAF 7/128 reads (5%) | catalogued as COSV62878826; called by muse, mutect2
- NKX2-4 | c.783C>A p.G261= | Silent (SNP) | VAF 10/11 reads (91%) | catalogued as COSV100698635; called by muse, mutect2, varscan2
- NLRP12 | c.2916C>T p.L972= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as COSV100145926; called by muse, mutect2, varscan2
- NOX4 | c.486G>C p.L162= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99631893; called by muse, mutect2, varscan2
- NPY1R | c.330G>A p.E110= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs768758335, COSV99649076; called by muse, mutect2, varscan2
- OCIAD1 | c.492C>T p.F164= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV99971288; called by muse, mutect2, varscan2
- OGFOD1 | c.579G>A p.P193= | Silent (SNP) | VAF 37/201 reads (18%) | catalogued as rs145169317, COSV100273171; called by muse, mutect2, varscan2
- OGT | c.1170C>T p.I390= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1428294469, COSV101035633; called by muse, mutect2, varscan2
- OLFM2 | c.342C>G p.L114= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV99321976, COSV99322050; called by muse, mutect2
- OR1J2 | c.51C>A p.L17= | Silent (SNP) | VAF 37/217 reads (17%) | catalogued as COSV100093409; called by muse, mutect2, varscan2
- OR4K1 | c.159C>A p.S53= | Silent (SNP) | VAF 86/403 reads (21%) | catalogued as COSV99579391, COSV99579456; called by muse, mutect2, varscan2
- OR4M1 | c.54C>A p.S18= | Silent (SNP) | VAF 102/787 reads (13%) | catalogued as COSV100271521; called by muse, mutect2, varscan2
- OR56A4 | c.1026G>T p.L342= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs374444209; called by mutect2, varscan2
99 further variants in this file (0 protein-altering or splice-affecting, 86 silent, 13 other) are not listed here.
